Somatic mutation profile of tumor specimen TCGA-QH-A65V-01A (aliquot TCGA-QH-A65V-01A-11D-A29Q-08) from TCGA case TCGA-QH-A65V, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 43.4 years (15,850 days).
Specimen TCGA-QH-A65V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06427a93-269d-4959-94e8-c02f098bd544.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A65V-10A (Blood Derived Normal), aliquot TCGA-QH-A65V-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eab6e531-f70f-4352-8b36-47242df27b74

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 3, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4543C>T p.R1515C | Missense Mutation (SNP) | VAF 25/77 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50560816, COSV50584645; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- HYLS1 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54993340; called by muse, mutect2, varscan2
- KCNAB2 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV51239293; called by muse, mutect2, varscan2
- LONP2 | c.896A>C p.K299T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV53527177; called by muse, mutect2, varscan2
- MID1IP1 | c.119A>T p.D40V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61231200; called by muse, mutect2, varscan2
- NCKAP1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757520353, COSV100720249, COSV62942413; called by muse, mutect2
- NOTCH2 | c.2605C>T p.R869W | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as rs587730290, COSV56680341; called by muse, mutect2, varscan2
- OR5AS1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV57983686; called by muse, mutect2, varscan2
- PCLO | c.11111C>T p.T3704M | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as rs530909855, COSV61615896; called by muse, mutect2, varscan2
- PRAMEF18 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1442335924; called by muse, varscan2
- PSME3 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as COSV53200542; called by muse, mutect2, varscan2
- PWWP2B | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770267148, COSV59450508; called by muse, mutect2, varscan2
- SND1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61250853; called by muse, mutect2, varscan2
- TERB2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs369672721; called by muse, mutect2, varscan2
- TNC | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1223837815, COSV60791837; called by muse, mutect2, varscan2
- TRPV6 | c.1577T>C p.I526T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs887979827, COSV63894144; called by muse, mutect2
- TTN | c.18217A>G p.K6073E (on ENST00000591111; = p.K5146E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/53 reads (8%) | PolyPhen possibly damaging (0.654); catalogued as rs1220495372; called by muse, mutect2
- UNC13D | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1331683767, COSV52888205; called by muse, mutect2, varscan2
- ZBED9 | c.3334T>C p.F1112L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.899); catalogued as COSV71729827; called by muse, mutect2, varscan2
- ZC3H15 | c.1054C>G p.L352V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV61923843; called by muse, mutect2, varscan2
- SHROOM2 | c.2087C>A p.S696Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- XG | c.18del p.L7Ffs*10 | Frame Shift Del (DEL) | VAF 34/167 reads (20%) | called by mutect2, pindel, varscan2
- CD40 | c.294A>G p.E98= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV64848365; called by muse, mutect2, varscan2
- COL5A2 | c.4470C>T p.G1490= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs142895373; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZC3H13 | c.45T>C p.T15= | Silent (SNP) | VAF 53/160 reads (33%) | catalogued as rs762210196, COSV54465561; called by muse, mutect2, varscan2
- STAG3L4 | n.338T>G | RNA (SNP) | VAF 56/141 reads (40%) | called by muse, mutect2, varscan2
